Somatic mutation profile of tumor specimen TARGET-50-PAKFYV-01A (aliquot TARGET-50-PAKFYV-01A-01D) from TARGET case TARGET-50-PAKFYV, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.4 years (1,246 days).
Specimen TARGET-50-PAKFYV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97e4724a-d886-4950-8b81-4f979417a70d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAKFYV-10A (Blood Derived Normal), aliquot TARGET-50-PAKFYV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e96f3dc-73fe-488b-a8df-2dfe43922b38

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 29/83 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs375338359, CM098494, COSV52690857, COSV52980226, COSV53438718; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 52/100 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPRD | c.2013del p.K671Nfs*17 | Frame Shift Del (DEL) | VAF 48/136 reads (35%) | catalogued as COSV100645110; called by mutect2, pindel, varscan2
- TTC3 | c.3566C>T p.T1189I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.235); catalogued as rs868763242; called by muse, mutect2, varscan2
- CMKLR1 | c.567C>A p.C189* (on ENST00000312143 / NM_001142344.2; = p.C187* on NM_004072.3) | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
